Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4IB, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4IB-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 3

BIRTHDATE:

PAT TYPE:

SEX: F

ADM DATE:

OPER DATE:

PROCEDURE: SPHS

year-old female identified on routine physical exam to have a thyroid nodule in

PROCEDURE: SPGD

1. "Total thyroid". Received in formalin in a small container is a 25 gram total thyroid, right lobe 4.7 x 2.7 x 1.3 cm and left lobe, 4.6 x 3.6 x 2.6 cm. The right lobe is inked blue with the left lobe inked black. Specimen is partially covered by a tan-grey capsule. The cut surface is a red-brown granular thyroid parenchyma that is remarkable for a 3.2 x 2.6 x 1.7 cm brown-tan ill-defined tumor in the left lower pole with extension to the left upper pole that extends to the capsule. The tumor is centrally necrotic and cystic.

1A-C. Right lobe superior to inferior.

1D. Isthmus.

1E-H. Left lobe superior to inferior with tumor.

2. "Level VI". Received in formalin in a small container is a 2.1 x 2.1 x 1.2 cm aggregate of yellow adipose. Multiple possible lymph nodes are identified ranging up to 1.1 cm.

2A. Multiple possible lymph nodes.

2B. One bisected possible lymph nodes. Fat retained.

PROCEDURE: SPMI

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 3.2 cm

Location(s): Left lobe

Capsular Invasion: Yes

Vascular Invasion: No

Margins: Negative

Extrathyroidal extension: No

Lymph node metastases: Yes

Extranodal extension: No

1C5-0-3

Carcinoma, papillary, thyroid, 8260/3

Site: thyroid, nos C73.9

hw
10/1/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #:

4

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Not specified	VI	2	7
Total Level	All	2	7

PROCEDURE: SPDX

1. Thyroid, total thyroidectomy: Papillary thyroid carcinoma (3.2 cm) confined to the thyroid. Capsular invasion present. Angiolymphatic invasion not identified. Margins free. Please see template. Mild lymphocytic thyroiditis.

2. Soft tissue of neck, side not specified, level VI, excision: Metastatic papillary thyroid carcinoma in two of seven lymph nodes. Extranodal extension not identified.

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 16ec5faa-e3a4-486f-b6d7-d94e25839952 (TCGA-KS-A4IB.53A2A6C2-4847-459F-8881-E4C37FEF9D9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).